Somatic mutation profile of tumor specimen TARGET-40-PALFYN-01A (aliquot TARGET-40-PALFYN-01A-01D) from TARGET case TARGET-40-PALFYN, project TARGET-OS (Osteosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 13.3 years (4,841 days).
Specimen TARGET-40-PALFYN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f80a2dc2-ddcb-4169-a7ad-fb23252b8cb8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-PALFYN-10A (Blood Derived Normal), aliquot TARGET-40-PALFYN-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/16211f19-371f-4828-b1a3-6f5873af0591

The open-access MAF lists 27 somatic variants for this specimen: 17 protein-altering or splice-affecting, 4 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Intron 4, Silent 4, RNA 1, Nonsense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CENPJ | c.3940C>T p.Q1314* | Nonsense Mutation (SNP) | VAF 15/85 reads (18%) | catalogued as rs1566275147; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNTNAP5 | c.3214G>A p.G1072R | Missense Mutation (SNP) | VAF 41/229 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs772641478, COSV70475477; called by muse, mutect2, varscan2
- DOCK9 | c.3571G>A p.A1191T (on ENST00000376460 / NM_001366676.2; = p.A1192T on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/184 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as rs55889102; called by muse, mutect2
- GALNT3 | c.161G>A p.R54K | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.8); PolyPhen benign (0.021); catalogued as rs1489357988; called by muse, mutect2, varscan2
- IGF2R | c.6100A>G p.K2034E | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.66); PolyPhen benign (0.021); catalogued as rs1408527688; called by muse, mutect2, varscan2
- KSR2 | c.821C>T p.P274L | Missense Mutation (SNP) | VAF 24/178 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as rs753606177, COSV60376257; called by muse, mutect2, varscan2
- OR2T34 | c.198C>G p.F66L | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as COSV100170581; called by muse, mutect2, varscan2
- PBRM1 | c.2032C>T p.R678C | Missense Mutation (SNP) | VAF 42/64 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1422119249, COSV56278883; called by muse, mutect2, varscan2
- PRKD1 | c.1216C>G p.L406V | Missense Mutation (SNP) | VAF 29/145 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as COSV100120215; called by muse, mutect2, varscan2
- REXO5 | c.218C>T p.A73V | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.362); catalogued as rs866190099; called by muse, mutect2
- RPL10L | c.423G>T p.K141N | Missense Mutation (SNP) | VAF 83/169 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as rs1368957216; called by muse, mutect2, varscan2
- GLDC | c.623A>C p.Q208P | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.46); called by muse, mutect2
- HNF1B | c.1658C>G p.P553R | Missense Mutation (SNP) | VAF 16/145 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- OR56A1 | c.321G>T p.M107I | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PCSK9 | c.1119C>A p.S373R | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- POLG | c.536G>T p.G179V | Missense Mutation (SNP) | VAF 30/36 reads (83%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.669); called by muse, mutect2, varscan2
- PRR33 | c.1408A>C p.N470H | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADCY7 | c.1299G>A p.G433= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as rs1408708807; called by muse, mutect2
- BRD9 | c.165G>A p.R55= | Silent (SNP) | VAF 8/71 reads (11%) | called by muse, mutect2, varscan2
- DTX1 | c.1348C>T p.L450= | Silent (SNP) | VAF 10/150 reads (7%) | called by muse, mutect2
- LTN1 | c.2784A>G p.L928= | Silent (SNP) | VAF 10/27 reads (37%) | called by muse, mutect2, varscan2
- AP3D1 | c.1860-37C>T | Intron (SNP) | VAF 19/50 reads (38%) | called by muse, mutect2
- ATXN2L | c.*673G>C | 3'UTR (SNP) | VAF 12/28 reads (43%) | called by muse, mutect2, varscan2
- DCAF10 | c.1311+142G>A | Intron (SNP) | VAF 6/12 reads (50%) | called by muse, mutect2, varscan2
- FAM3D | c.264-23T>C | Intron (SNP) | VAF 33/62 reads (53%) | called by muse, mutect2, varscan2
- IFITM8P | n.251T>C | RNA (SNP) | VAF 16/282 reads (6%) | called by muse, mutect2
- ZNF302 | c.10-61C>A | Intron (SNP) | VAF 9/91 reads (10%) | called by muse, mutect2
